MMRF case MMRF_2072 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/09d67a3e-d4d7-4a96-84c7-0c3af1d4a1da

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.3 years (26,758 days); ISS stage: I; Days to last known disease status: 828 days (2.3 years); Days to last follow up: 828 days (2.3 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 15 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 37 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 16 days; Days to treatment end: 36 days.
   Treatment given: Therapeutic agents: Lenalidomide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 50 days; Days to treatment end: 197 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 57 days; Days to treatment end: 140 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 141 days; Days to treatment end: 197 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 198 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 103 mg/dL; Immunoglobulin G 7.29 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.68 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 292 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L; C-Reactive Protein 0.072 mg/dL.
- Day 92: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 6.5 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.72 g/L; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 7.3 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 7.37 mmol/L.
- Day 170 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 6.64 g/L; Immunoglobulin A 1.4 g/L; Immunoglobulin M 0.82 g/L; Lactate Dehydrogenase 3.95 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 12.4 ×10⁹/L; Absolute Neutrophil 11.9 ×10⁹/L; Platelets 414 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 8.58 mmol/L.
- Day 254: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 7.67 g/L; Immunoglobulin A 1.59 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 5.9 g/dL; Glucose 5.83 mmol/L.
- Day 366: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 9.61 g/L; Immunoglobulin A 2.29 g/L; Immunoglobulin M 0.86 g/L; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 289 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 4.62 mmol/L.
- Day 436 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 9.97 g/L; Immunoglobulin A 3.18 g/L; Immunoglobulin M 0.87 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 327 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 4.95 mmol/L.
- Day 633 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 3.06 g/L; Immunoglobulin M 0.79 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 6.55 mmol/L.
- Day 716 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 2.91 g/L; Immunoglobulin M 0.8 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 8.8 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 6.16 mmol/L.
- Day 828: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.99 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 2.76 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 6.11 mmol/L.

Other clinical attributes
- Day -17: Weight: 55 kg; Height: 154 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2072_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_2072_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
